Gene-level copy-number profile of tumor specimen TCGA-TM-A84I-01A from TCGA case TCGA-TM-A84I, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 30.7 years (11,221 days).
Specimen TCGA-TM-A84I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.07916b21-6798-45b8-84d3-daa46acf8fb3.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,856 have no estimate.
https://portal.gdc.cancer.gov/files/f8e64e1a-2371-4027-801a-27308ac55b2b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 4,018; copy number 3: 10,669; copy number 4: 35,137; copy number 5: 5,726; copy number 6: 205; copy number 7: 1,009.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TM-A84I-01A-11D-A36N-01): tumor purity 0.85, ploidy 3.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
